Somatic mutation profile of tumor specimen MP2PRT-PASXFR-TMP1-A (aliquot MP2PRT-PASXFR-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASXFR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,986 days).
Specimen MP2PRT-PASXFR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6a75bbb-d7d7-4a20-a490-c877ee9b12f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASXFR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASXFR-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cacef39e-c504-4dfa-958b-8b9a53ccaee6

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 1, Translation Start Site 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA2 | c.2261A>G p.E754G | Missense Mutation (SNP) | VAF 191/437 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755243275; called by muse, mutect2, varscan2
- CACNA2D3 | c.1355G>C p.W452S | Missense Mutation (SNP) | VAF 73/385 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55558244; called by muse, mutect2, varscan2
- CCDC168 | c.12676G>T p.V4226F | Missense Mutation (SNP) | VAF 41/664 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.6); catalogued as rs1218627645; called by muse, mutect2
- CDH10 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 115/323 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52576756; called by muse, mutect2, varscan2
- TUBA3C | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 109/334 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.139); catalogued as rs766373810; called by muse, mutect2, varscan2
- ATP13A5 | c.2344A>T p.S782C | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- BCORL1 | c.4261A>T p.K1421* | Nonsense Mutation (SNP) | VAF 132/163 reads (81%) | called by muse, mutect2, varscan2
- DUOX1 | c.2593T>G p.F865V | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- ERC2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 72/200 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- FAM71E1 | c.469G>C p.A157P (on ENST00000600100 / NM_001308429.2; = p.A141P on NM_138411.3) | Missense Mutation (SNP) | VAF 162/451 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- GMPS | c.126C>G p.D42E | Missense Mutation (SNP) | VAF 23/469 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2
- LPA | c.1206T>G p.H402Q | Missense Mutation (SNP) | VAF 130/1021 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRRC49 | c.1490C>G p.T497R | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MUC12 | c.2689T>A p.F897I (on ENST00000379442; = p.F754I on NM_001164462.1) | Missense Mutation (SNP) | VAF 272/892 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.316); called by muse, mutect2
- PEG3 | c.1694G>A p.C565Y | Missense Mutation (SNP) | VAF 123/454 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R10 | c.1035G>C p.E345D | Missense Mutation (SNP) | VAF 74/657 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PRAMEF14 | c.590del p.K197Sfs*3 | Frame Shift Del (DEL) | VAF 63/341 reads (18%) | called by mutect2, pindel, varscan2
- SEMA4G | c.734G>C p.R245P | Missense Mutation (SNP) | VAF 129/407 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TDP1 | c.971T>G p.I324S | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2
- TEX13D | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- UBAC1 | c.1114A>C p.M372L | Missense Mutation (SNP) | VAF 125/304 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ZMYM2 | c.4034_4035insCTCC p.L1346Sfs*22 | Frame Shift Ins (INS) | VAF 55/319 reads (17%) | called by mutect2, varscan2*
- FREM1 | c.1443T>C p.V481= | Silent (SNP) | VAF 121/310 reads (39%) | called by muse, mutect2, varscan2
- IL12B | c.510C>T p.C170= | Silent (SNP) | VAF 107/265 reads (40%) | catalogued as rs771036480, COSV51454347; called by muse, mutect2, varscan2
- IL18RAP | c.1563G>A p.E521= | Silent (SNP) | VAF 83/420 reads (20%) | catalogued as rs540633615; called by muse, mutect2, varscan2
- LRP12 | c.2049G>A p.T683= | Silent (SNP) | VAF 208/425 reads (49%) | catalogued as rs371920844, COSV99408522; called by muse, mutect2, varscan2
- ST7 | c.1737A>G p.Q579= | Silent (SNP) | VAF 118/299 reads (39%) | catalogued as rs750412006, COSV55380168; called by muse, mutect2, varscan2
- UGT2B17 | c.1383A>T p.A461= | Silent (SNP) | VAF 96/197 reads (49%) | called by muse, mutect2, varscan2
- UNC5A | c.1446G>T p.L482= | Silent (SNP) | VAF 22/538 reads (4%) | called by muse, mutect2
